Somatic mutation profile of tumor specimen 0DHQFG from CCDI case PBBUXS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 4.2 years (1,531 days).
Specimen 0DHQFG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a1673b8-780a-4921-8b20-878ebda85627.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHQDI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1c03500-66dd-44b8-abc6-bfac322e35c5

The open-access MAF lists 24 somatic variants for this specimen: 22 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Nonsense Mutation 2, Frame Shift Del 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS7 | c.2890C>T p.R964C | Missense Mutation (SNP) | VAF 85/556 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs769713958, COSV66308373; called by muse, mutect2, varscan2
- CHRM2 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 230/481 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1455067791, COSV57774807; called by muse, mutect2, varscan2
- ENDOU | c.285C>G p.Y95* (on ENST00000422538 / NM_001172439.2; = p.Y54* on NM_006025.4) | Nonsense Mutation (SNP) | VAF 297/711 reads (42%) | catalogued as rs377067870; called by muse, mutect2, varscan2
- FDXR | c.1009G>A p.D337N (on ENST00000293195 / NM_024417.5; = p.D343N on NM_004110.6) | Missense Mutation (SNP) | VAF 79/760 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1453805719; called by muse, mutect2, varscan2
- FLT1 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 119/597 reads (20%) | catalogued as rs1244106213, COSV56733174; called by muse, mutect2, varscan2
- GPAT4 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 136/326 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101214120; called by muse, mutect2, varscan2
- LGR6 | c.2531G>A p.R844H (on ENST00000367278 / NM_001017403.1; = p.R792H on NM_021636.3) | Missense Mutation (SNP) | VAF 38/634 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as rs374809410; called by muse, mutect2
- MYH2 | c.5476C>T p.R1826W | Missense Mutation (SNP) | VAF 64/445 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs755265718; called by muse, mutect2, varscan2
- P2RY4 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 209/512 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs758352422; called by muse, mutect2, varscan2
- PTPRN | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 177/403 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs373770554; called by muse, mutect2, varscan2
- RADIL | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 50/524 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs778018782; called by muse, mutect2
- TBK1 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 46/526 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV99045321; called by muse, mutect2
- TKTL1 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 28/814 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs1557172314; called by muse, mutect2
- CCDC177 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, varscan2
- CMAS | c.892A>G p.K298E | Missense Mutation (SNP) | VAF 200/457 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IMPDH1 | c.1414del p.A472Pfs*10 (on ENST00000470772 / NM_001142573.2; = p.A558Pfs*10 on NM_000883.4) | Frame Shift Del (DEL) | VAF 66/610 reads (11%) | called by mutect2, pindel, varscan2
- LRRC36 | c.1037G>T p.S346I | Missense Mutation (SNP) | VAF 23/668 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- MAGED1 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 14/451 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- PARP10 | c.2032G>C p.A678P | Missense Mutation (SNP) | VAF 86/570 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PHKA1 | c.2227C>G p.Q743E | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMC8 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 15/424 reads (4%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2
- TNFRSF4 | c.800A>T p.Q267L | Missense Mutation (SNP) | VAF 21/393 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.228); called by muse, mutect2
- ZNF275 | c.1170C>T p.S390= | Silent (SNP) | VAF 39/308 reads (13%) | catalogued as rs368558325; called by muse, mutect2, varscan2
- COG7 | c.*81C>A | 3'UTR (SNP) | VAF 63/251 reads (25%) | called by muse, mutect2, varscan2
